Gene-level copy-number profile of tumor specimen ALCH-B4CH-TTP1-B from ALCHEMIST case ALCH-B4CH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.1 years (24,491 days).
Specimen ALCH-B4CH-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 582d8e13-5770-44e8-b617-1f973bc1aa20.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4CH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/277ffe87-7e30-43c6-80b4-c119fe6306ea

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 482; copy number 1: 1,440; copy number 2: 12,674; copy number 3: 18,668; copy number 4: 20,245; copy number 5: 4,268; copy number 6: 930; copy number 7: 52; copy number 13: 2; copy number 21: 14; copy number 24: 69; copy number 28: 10; copy number 29: 43; copy number 33: 14.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,190,901–7,191,563, 1 gene: RPS3AP33.
- chr8:12,095,176–12,115,516, 2 genes: DEFB108D, ZNF705D.
- chr8:12,128,107–12,134,099, 2 genes (within-gene range 0–1): AC130366.1, USP17L7.
- chr19:18,001,132–18,014,102, 2 genes: ARRDC2, AC020904.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 152 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:53,559,214–62,275,678, 150 genes, copy number 21–33 (broad region; genes not listed).
- chr7:65,773,620–65,814,775, 2 genes, copy number 13: GTF2IP5, RNU6-912P.

Autosomal genes at a single copy (total copy number 1): 1,403. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
